Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JH, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JH-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating, ductal, NOS 8500/3
Site: breast, NOS C50.9 3/1/11 lw

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.: /

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast and axillary tissue

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast.

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on

Macroscopic description:

Right breast sized 14 x 14.5 x 2.5 cm removed along with axillary tissues sized 11 x 4.5 x 2 cm and a 11 x 5.6 cm skin flap. Weight 260 g.

Tumour sized 1,2 x 10 x 1,0 cm found in the outer lower quadrant, 0.9 cm from the lower boundary, 0.5 cm from the base and less than 0.1 cm from the parenchyma.

Lymph nodes 1.8 cm in length.

Microscopic description:

Carcinoma ductale invasivum – NHG1 (2 + 2 +1: 5 mitoses/ 10 HPF, visual area diameter: 0.55 m).

Calcifications within the tumour.

Mamilla sine laesionibus.

Glandular tissue showing lesions of the type mastopathia fibrosa (fibrocystic changes).

Invasive lesions reaching the base.

AXILLARY LYMPH NODES

Lymphonodulitis chronica et sinis histiocytosis No IX.

Histopathology diagnosis:

Carcinoma ductale invasivum mammae dextrae. (NHG1, pT1c, pN0). Invasive ductal carcinoma of the right breast

Reviewed In (Initial):		

Compliance validated by:

3/1/11

Source: NCI Genomic Data Commons file 4f04049d-1bea-4d6d-8480-908ab905f7d1 (TCGA-D8-A1JH.49C79E09-2F69-4089-BFB1-53197DA09A46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).